Somatic mutation profile of tumor specimen TCGA-AZ-4684-01A (aliquot TCGA-AZ-4684-01A-01D-1408-10) from TCGA case TCGA-AZ-4684, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 50.0 years (18,252 days).
Specimen TCGA-AZ-4684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b342e270-4fa0-4e1c-9325-c23a12c28a87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4684-10A (Blood Derived Normal), aliquot TCGA-AZ-4684-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee5599f-7608-467f-a52a-1dbcfa359c08

The open-access MAF lists 85 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 24, Nonsense Mutation 7, Intron 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3982C>T p.Q1328* | Nonsense Mutation (SNP) | VAF 52/83 reads (63%) | hotspot (GDC flag); catalogued as rs398123121, CM930028, COSV57324976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C8B | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 93/174 reads (53%) | catalogued as rs140813121, CM952411, COSV64778579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 38/60 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs782598285; called by muse, mutect2, varscan2
- ACTL7B | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV65927739; called by muse, mutect2
- ADGRB1 | c.3019A>G p.N1007D | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV60097156; called by muse, mutect2, varscan2
- ANKRD12 | c.5741G>A p.R1914H | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1480233775; called by muse, mutect2, varscan2
- ATP6V1C2 | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763804757, COSV55360671, COSV55362051; called by muse, mutect2, varscan2
- BMP1 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746954049; called by muse, mutect2, varscan2
- BPI | c.1379C>T p.T460M (on ENST00000262865; = p.T456M on NM_001725.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs148829027; called by muse, mutect2, varscan2
- C2orf16 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV68646179; called by muse, mutect2, varscan2
- CACNA1E | c.3773G>T p.R1258L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62382257; called by muse, mutect2, varscan2
- CSMD2 | c.4195G>C p.D1399H | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV53943142; called by muse, mutect2, varscan2
- DCAF4L2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1160347234, COSV60479615, COSV60480142; called by muse, mutect2
- DGKQ | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.227); catalogued as rs576225867; called by muse, mutect2, varscan2
- FERMT2 | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.928); catalogued as rs775328997, COSV58407302; called by muse, mutect2, varscan2
- GPR176 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 31/48 reads (65%) | catalogued as rs781230494; called by muse, mutect2, varscan2
- HAGHL | c.758C>T p.A253V (on ENST00000341413; = p.G215= on NM_032304.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV52401738; called by muse, mutect2, varscan2
- HECTD4 | c.8212G>A p.E2738K | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66392587; called by muse, mutect2, varscan2
- ILKAP | c.532+1G>A p.X178_splice | Splice Site (SNP) | VAF 35/98 reads (36%) | catalogued as COSV54518405; called by muse, mutect2, varscan2
- MAML1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV52985693; called by muse, mutect2, varscan2
- MAST4 | c.6235G>A p.V2079M (on ENST00000403625 / NM_001164664.2; = p.V1890M on NM_015183.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as rs763506787; called by muse, mutect2, varscan2
- MON1A | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as rs1370325523, COSV56560706; called by muse, mutect2, varscan2
- NEB | c.15806C>A p.T5269K | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51420501; called by muse, mutect2, varscan2
- NMBR | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs918071854; called by muse, mutect2
- NT5DC3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as rs766572518, COSV67322238, COSV67322749; called by muse, mutect2, varscan2
- OR5F1 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99558854; called by muse, mutect2, varscan2
- PAX1 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV68271990; called by muse, mutect2, varscan2
- PPFIA4 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs780862151, COSV99829953; called by muse, mutect2, varscan2
- RBMS1 | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV62353425; called by muse, mutect2, varscan2
- RREB1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1448038862; called by muse, mutect2
- SCN11A | c.2253G>A p.M751I | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756498208, COSV100182806; called by muse, mutect2, varscan2
- SCNN1G | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV100264516; called by muse, mutect2, varscan2
- SYNE1 | c.509G>A p.R170Q (on ENST00000367255 / NM_182961.4; = p.R177Q on NM_033071.3) | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779239788; called by muse, mutect2, varscan2
- TUBA3C | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as rs139914455, COSV67139666; called by muse, mutect2, varscan2
- ANKS1B | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BORA | c.713A>T p.D238V (on ENST00000613797; = p.D163V on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARNMT1 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CPD | c.1912C>A p.P638T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DDX10 | c.788T>G p.L263R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX60 | c.3240A>C p.L1080F | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2
- DGCR8 | c.1231_1241del p.L411Gfs*19 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- FAN1 | c.2234C>G p.S745* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- KDM1B | c.2332dup p.E778Gfs*8 (on ENST00000449850; = p.E545Gfs*8 on NM_153042.4) | Frame Shift Ins (INS) | VAF 8/77 reads (10%) | called by mutect2, pindel
- LRRC8B | c.209G>C p.W70S | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MCM4 | c.1353A>C p.E451D | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MOCS3 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC2 | c.4152A>G p.I1384M | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- NAB1 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAGPA | c.1206C>A p.C402* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2
- RMI1 | c.1277A>T p.K426I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RNASEH1 | c.567A>T p.A189= | Splice Region (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.7316C>T p.A2439V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM147 | c.287A>T p.E96V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); called by muse, mutect2
- VPS13A | c.8176C>T p.L2726F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZBTB26 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF226 | c.1916G>C p.G639A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP13A4 | c.1098C>A p.A366= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs367828072; called by muse, mutect2, varscan2
- ATXN1 | c.1068C>T p.Y356= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs537873773, COSV55217204; called by muse, mutect2, varscan2
- BPGM | c.642T>A p.T214= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- CENPF | c.4428G>A p.L1476= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- CREB3L3 | c.1062G>A p.A354= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs201642168; called by muse, mutect2, varscan2
- CTNNA2 | c.939C>T p.G313= | Silent (SNP) | VAF 50/84 reads (60%) | catalogued as rs370498426, COSV100782546; called by muse, mutect2, varscan2
- GPC1 | c.384C>T p.G128= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs760797736; called by muse, mutect2, varscan2
- GPR17 | c.852C>T p.S284= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs1167205650, COSV55754037, COSV99760667; called by muse, mutect2, varscan2
- HDAC4 | c.27A>T p.G9= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- ITGA3 | c.2986C>T p.L996= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- ITPRIPL1 | c.1242C>T p.P414= (on ENST00000439118 / NM_001008949.3; = p.P422= on NM_178495.6) | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs754055738, COSV63152688; called by muse, mutect2, varscan2
- KHDRBS3 | c.834T>G p.A278= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- MXRA5 | c.6288C>T p.H2096= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as rs764679864, COSV54232781, COSV54241748; called by muse, mutect2, varscan2
- NR3C1 | c.2247C>T p.F749= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as COSV99196140; called by muse, mutect2, varscan2
- PCDHB6 | c.1566G>T p.L522= | Silent (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- PEAK1 | c.4272C>T p.D1424= | Silent (SNP) | VAF 49/74 reads (66%) | catalogued as rs770564562, COSV56940465; called by muse, mutect2, varscan2
- RRNAD1 | c.1104C>T p.H368= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs780937498; called by muse, mutect2, varscan2
- RYR2 | c.1119T>G p.T373= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs202231354, COSV100767104, COSV63675113; called by muse, mutect2, varscan2
- SALL1 | c.3771C>T p.N1257= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs145423593, COSV51765533; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC16A | c.4719G>A p.S1573= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs776375201, COSV51528966; called by muse, mutect2
- SEMA4G | c.1158C>G p.G386= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- SGCG | c.642C>T p.H214= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs528994151, COSV54561453; called by muse, mutect2, varscan2
- SYNJ2 | c.1590C>T p.I530= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV62899518, COSV62900134, COSV62900655; called by muse, mutect2, varscan2
- TAF4 | c.1500C>T p.P500= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs764367337, COSV53334342; called by mutect2, varscan2
- EDEM2 | c.*2C>G | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2
- PALM2AKAP2 | c.400+6916C>T | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as rs748723983; called by muse, mutect2, varscan2
- TTN | c.10361-4574C>A | Intron (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
